Somatic mutation profile of tumor specimen BA2174D (aliquot aq-BA2174D) from BEATAML1.0 case 2341, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.4 years (16,963 days).
Specimen BA2174D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e355597-bccf-460c-8d96-cc948ae4159a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2141D (Solid Tissue Normal), aliquot aq-BA2141D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/943bf1e1-f6ec-46f0-a732-bdc0f5d802b1

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1496G>T p.W499L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99171504; called by muse, mutect2
- FER1L6 | c.2330T>C p.V777A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs1266129283; called by muse, varscan2
- LARGE1 | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.014); catalogued as rs1481014953; called by muse, mutect2
- OBSCN | c.12512C>T p.T4171M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); catalogued as rs778801081, COSV52788497; called by muse, mutect2, varscan2
- PCDH17 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs371189468; called by muse, mutect2, varscan2
- POLQ | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1288320990; called by muse, mutect2, varscan2
- AEBP2 | c.988T>C p.C330R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); called by muse, mutect2
- AQP8 | c.22T>C p.C8R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARL6IP6 | c.137A>G p.E46G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GNG7 | c.82-1G>T p.X28_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- ITGB6 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2
- LDB1 | c.999+2T>C p.X333_splice (on ENST00000425280 / NM_001321612.2; = p.V298A on NM_003893.5) | Splice Site (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- PLXDC2 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SBSPON | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); called by muse, mutect2
- SLC25A42 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- TSPAN7 | c.349A>C p.K117Q | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ZNF407 | c.5278C>A p.H1760N | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF416 | c.1459A>G p.T487A | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- DCLRE1A | c.3051T>C p.N1017= | Silent (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
- DCP2 | c.69T>C p.H23= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs112366745; called by muse, mutect2, varscan2
- SUPV3L1 | c.768T>C p.G256= | Silent (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- ZBTB11 | c.603A>G p.L201= | Silent (SNP) | VAF 37/238 reads (16%) | called by muse, mutect2, varscan2
- MSL3P1 | n.820A>G | RNA (SNP) | VAF 34/81 reads (42%) | called by mutect2, varscan2
